Somatic mutation profile of tumor specimen TCGA-MO-A47R-01A (aliquot TCGA-MO-A47R-01A-11D-A24N-09) from TCGA case TCGA-MO-A47R, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 75.9 years (27,731 days).
Specimen TCGA-MO-A47R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b67d76c-20f9-4f5f-a63a-028bbde233b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MO-A47R-10A (Blood Derived Normal), aliquot TCGA-MO-A47R-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7caf769e-3202-489c-87e0-adb3c02020ba

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 3, Frame Shift Ins 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIITA | c.3317+1G>A p.X1106_splice | Splice Site (SNP) | VAF 29/97 reads (30%) | catalogued as rs771073292, CS971796, COSV60859769; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGA3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778114016, CM014539, COSV55624106, COSV99737274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs759189809; called by muse, mutect2, varscan2
- CCND1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs769921935; called by muse, varscan2
- COA3 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748728709, COSV55904088; called by muse, mutect2, varscan2
- CTC1 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV59853633; called by muse, mutect2, varscan2
- DNAH17 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs868532432, COSV67750733; called by muse, mutect2, varscan2
- HEBP1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs775966688; called by muse, mutect2, varscan2
- INTS9 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as rs750148696; called by muse, varscan2
- PDE4D | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.959); catalogued as rs772125696; called by muse, mutect2, varscan2
- PHLDB2 | c.2929C>T p.R977C (on ENST00000393925 / NM_001134439.2; = p.R934C on NM_145753.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs367905377; called by muse, mutect2, varscan2
- PIK3CA | c.2555G>A p.R852Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs199943173, COSV55937359; called by muse, mutect2, varscan2
- PSG8 | c.709+1G>A p.X237_splice | Splice Site (SNP) | VAF 53/174 reads (30%) | catalogued as rs533744633, COSV60614698; called by muse, mutect2, varscan2
- SOX9 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV99818861; called by muse, mutect2, varscan2
- TUBA3C | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.213); catalogued as rs1455284031; called by muse, mutect2, varscan2
- WNT9A | c.500dup p.C168Lfs*6 | Frame Shift Ins (INS) | VAF 28/80 reads (35%) | catalogued as rs779992922, COSV55293438; called by mutect2, varscan2
- ASPRV1 | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ASXL2 | c.2611T>A p.S871T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BRCA2 | c.655del p.T219Lfs*11 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- CASP4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ENTHD1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- FAM91A1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- FLG | c.5375C>T p.S1792F | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KIT | c.1669_1682del p.W557Gfs*18 | Frame Shift Del (DEL) | VAF 36/57 reads (63%) | called by mutect2, pindel*, varscan2*
- KMT2E | c.2987dup p.T997Dfs*8 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- MICAL3 | c.3137G>T p.R1046L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NUP205 | c.3713C>T p.A1238V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- OR52L1 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DOCK5 | c.1296C>G p.G432= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- PRX | c.1617G>A p.P539= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs546393524; called by muse, mutect2, varscan2
- SF3B3 | c.2142C>G p.A714= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- DCHS2 | n.4528A>G | RNA (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
